Somatic mutation profile of tumor specimen TCGA-RW-A7CZ-01A (aliquot TCGA-RW-A7CZ-01A-11D-A35D-08) from TCGA case TCGA-RW-A7CZ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 73.0 years (26,657 days).
Specimen TCGA-RW-A7CZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fff91ae7-2d9b-4cc1-bc4c-b52ca07d36a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RW-A7CZ-10B (Blood Derived Normal), aliquot TCGA-RW-A7CZ-10B-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/557b9b46-c2cf-4f48-aff2-3e4938b3a003

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Nonsense Mutation 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMCX3 | c.359C>G p.P120R | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV100362258; called by muse, mutect2, varscan2
- AWAT1 | c.581C>A p.T194N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs963144948; called by muse, mutect2
- JUN | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as rs1425026692; called by muse, mutect2, varscan2
- PLCH1 | c.1346A>G p.H449R (on ENST00000340059 / NM_001130960.2; = p.H461R on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs1471878281; called by muse, mutect2, varscan2
- PPP1R3F | c.2369C>T p.A790V | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs200780292, COSV99278644; called by muse, mutect2
- FBXO33 | c.615T>G p.F205L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SYT9 | c.813A>T p.K271N | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF426 | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- ABCF2 | c.1362C>T p.I454= | Silent (SNP) | VAF 14/122 reads (11%) | called by muse, mutect2, varscan2
- CSMD3 | c.11055C>T p.N3685= (on ENST00000297405 / NM_001363185.1; = p.N3516= on NM_052900.3) | Silent (SNP) | VAF 54/173 reads (31%) | catalogued as rs760587971, COSV52132235, COSV52260743; called by muse, mutect2, varscan2
- PCDHB10 | c.2280C>T p.G760= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs1161127076; called by muse, mutect2, varscan2
- SSH3 | c.1947C>T p.S649= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs373974857; called by muse, mutect2, varscan2
- PHACTR1 | c.664+2255C>A | Intron (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- WASF4P | n.61G>A | RNA (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
